Somatic mutation profile of tumor specimen 0DR7Y9 from CCDI case PBCGFJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.0 years (2,915 days).
Specimen 0DR7Y9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0585bec-6363-44af-a0ea-bbc565cd7e3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR7YG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e729bef0-3a68-4ff5-9484-bfe038fa0762

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 5'Flank 1, RNA 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 489/1145 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.2066G>A p.R689Q (on ENST00000281708 / NM_001349798.2; = p.R609Q on NM_018315.5) | Missense Mutation (SNP) | VAF 448/1306 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55900091; called by muse, varscan2
- KDM6A | c.3835C>T p.R1279* | Nonsense Mutation (SNP) | VAF 455/1262 reads (36%) | catalogued as rs863224886, CM162445, COSV65037841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 272/601 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as rs1479205325; called by muse, mutect2, varscan2
- CYP3A43 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 460/1077 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541842153, COSV99733809; called by muse, mutect2, varscan2
- DDX3X | c.1048C>T p.R350W (on ENST00000399959; = p.R351W on NM_001356.5) | Missense Mutation (SNP) | VAF 426/1141 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67864267; called by muse, mutect2, varscan2
- NOTCH2 | c.989G>C p.W330S | Missense Mutation (SNP) | VAF 53/1190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56707550; called by muse, mutect2
- BMP2K | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 351/775 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 48/1840 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- SMARCA1 | c.1550T>G p.I517S | Missense Mutation (SNP) | VAF 700/1694 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AHNAK2 | c.6264C>G p.G2088= | Silent (SNP) | VAF 301/370 reads (81%) | called by muse, mutect2, varscan2
- CACNA1E | c.2406G>A p.A802= | Silent (SNP) | VAF 282/808 reads (35%) | catalogued as rs1192075910, COSV62409847; called by muse, mutect2, varscan2
- ING1 | c.234C>T p.S78= | Silent (SNP) | VAF 351/897 reads (39%) | catalogued as COSV58172123; called by muse, mutect2, varscan2
- SETD1B | c.1549C>T p.L517= | Silent (SNP) | VAF 23/727 reads (3%) | catalogued as rs1356532770, COSV99930749; called by muse, mutect2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 12/249 reads (5%) | catalogued as rs1262556378; called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 18/608 reads (3%) | called by muse, mutect2
- URGCP | chr7:43906617 C>A | 5'Flank (SNP) | VAF 91/284 reads (32%) | called by muse, mutect2, varscan2
